FM case AD4365 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/d0d9fc7d-ebd1-4c80-92de-364fc4a1d8c8

Female, 47.5 years: Carcinoma, NOS (ICD-O-3 8010/3) of the breast; metastasis biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
